Gene-level copy-number profile of tumor specimen ALCH-B2W9-TTP1-A from ALCHEMIST case ALCH-B2W9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.6 years (22,865 days).
Specimen ALCH-B2W9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d5c1ba88-c73c-48af-b696-05948c14fd49.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2W9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/bd96d3bb-2142-4e69-82d9-fe4150351a76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 177; copy number 1: 3,531; copy number 2: 54,044; copy number 3: 616; copy number 4: 18; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 158 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,205,671–32,336,233, 11 genes (within-gene range 0–2): IQCC, DCDC2B, TMEM234, EIF3I, MTMR9LP, FAM167B, LCK, Metazoa_SRP, Y_RNA, HDAC1, MARCKSL1.
- chr1:167,052,551–167,166,479, 2 genes (within-gene range 0–2): AL158837.1, GPA33.
- chr1:180,912,897–180,951,614, 1 gene (within-gene range 0–2): KIAA1614.
- chr1:226,083,590–226,127,346, 2 genes: LINC01703, AL512343.1.
- chr2:61,575,774–61,605,722, 3 genes: AC016727.2, RPS29P10, RNU6-1145P.
- chr2:121,216,587–121,285,202, 1 gene: TFCP2L1.
- chr2:231,362,708–231,401,164, 3 genes (within-gene range 0–2): MIR4777, AC017104.1, B3GNT7.
- chr3:90,202,316–90,261,708, 2 genes: PROS2P, HSPE1P19.
- chr3:134,351,852–134,375,479, 3 genes: RPL39P5, AMOTL2, MIR6827.
- chr5:139,684,645–139,775,472, 5 genes: AC008667.1, RNU6-236P, PSD2-AS1, AC008667.3, AC008667.4.
- chr7:5,526,409–5,563,902, 3 genes (within-gene range 0–1): ACTB, AC006483.2, AC006483.1.
- chr7:27,128,969–27,250,493, 30 genes (within-gene range 0–2): AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7, AC004080.4, HOXA9, AC004080.3, HOXA10-AS, MIR196B, HOXA10, HOXA11, HOXA11-AS, AC004080.7, AC004080.14, AC004080.8, AC004080.2, AC004080.12, AC004080.15, AC004080.13, HOXA13, HOTTIP, AC004080.9, AC004080.16, AC004080.10, AC004080.11, AC004080.1, EVX1-AS, EVX1.
- chr7:65,960,684–66,094,697, 5 genes: GUSB, AC073261.1, AC068533.2, AC068533.1, ASL.
- chr7:76,389,334–76,541,459, 10 genes: SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr7:138,688,980–138,799,560, 3 genes (within-gene range 0–2): AC020983.1, UQCRFS1P2, ATP6V0A4.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr10:32,173,684–32,173,744, 1 gene: RNU7-22P.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr11:18,706,537–18,740,568, 1 gene (within-gene range 0–2): AC103974.1.
- chr11:34,189,174–34,189,275, 1 gene (within-gene range 0–2): Y_RNA.
- chr11:50,409,042–54,725,816, 12 genes: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:72,576,141–72,674,591, 5 genes (within-gene range 0–2): PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1.
- chr12:1,500,525–1,504,424, 1 gene: LINC00942.
- chr12:31,073,860–31,104,799, 2 genes: DDX11, SNORA75.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:24,332,310–24,340,022, 2 genes (within-gene range 0–2): AL096870.1, RIPK3.
- chr14:49,598,761–49,614,672, 3 genes (within-gene range 0–2): LRR1, RHOQP1, AL139099.3.
- chr14:64,704,102–64,750,249, 1 gene (within-gene range 0–2): PLEKHG3.
- chr14:90,489,010–90,491,637, 1 gene: AL096869.3.
- chr15:68,749,501–68,750,691, 1 gene: CARS1P1.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr16:31,975,803–32,003,728, 1 gene: AC142381.3.
- chr16:74,332,402–74,441,937, 6 genes (within-gene range 0–2): AC009053.1, AC009053.2, NPIPB15, AC009053.4, CLEC18B, AC009053.3.
- chr16:75,218,988–75,226,338, 1 gene (within-gene range 0–1): CTRB1.
- chr17:62,627,670–62,693,597, 4 genes (within-gene range 0–2): MRC2, Y_RNA, AC080038.3, RNU6-446P.
- chr19:17,215,346–17,282,786, 5 genes (within-gene range 0–2): USE1, OCEL1, NR2F6, AC010646.1, USHBP1.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr19:35,040,506–35,113,664, 3 genes (within-gene range 0–2): HPN, HPN-AS1, AC020907.1.
- chr22:36,066,533–36,093,352, 3 genes: Z95114.4, Z95114.1, Z95114.2.
- chr22:40,673,484–40,682,814, 2 genes: GAPDHP37, MCHR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:132,169,823–132,170,043, 1 gene, copy number 5: AC138466.3.
- chr16:90,173,217–90,222,851, 1 gene, copy number 5 (within-gene range 3–5): LINC02193.

Autosomal genes at a single copy (total copy number 1): 2,238. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
